Somatic mutation profile of tumor specimen CPT000817 (aliquot CPT000817-0010) from CPTAC case 100003304, project CPTAC-2 (Breast). Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 60.5 years (22,112 days).
Specimen CPT000817: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f2ab9fe-2435-43c3-a738-570d3298f2d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000823 (Blood Derived Normal), aliquot CPT000823-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6db00469-2842-45f5-aa83-7ceb8708c37d

The open-access MAF lists 107 somatic variants for this specimen: 70 protein-altering or splice-affecting, 25 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 25, Splice Site 4, Frame Shift Del 3, RNA 3, Intron 3, Nonsense Mutation 3, 3'UTR 2, In Frame Del 2, 5'UTR 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 49/76 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3043G>C p.E1015Q | Missense Mutation (SNP) | VAF 159/396 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV57050078; called by muse, mutect2, varscan2
- ACVR1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs370028017; called by muse, mutect2, varscan2
- ARFGEF1 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 53/197 reads (27%) | catalogued as COSV51603368, COSV99142296; called by muse, mutect2, varscan2
- ARSK | c.1597C>G p.P533A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV66169303; called by muse, mutect2, varscan2
- ASTL | c.732C>G p.S244R | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60903637; called by muse, mutect2, varscan2
- ATP4A | c.2006A>C p.K669T | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV52866059; called by muse, mutect2, varscan2
- AUP1 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57816181; called by muse, mutect2, varscan2
- B3GNT4 | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs780533004, COSV99928152; called by muse, mutect2, varscan2
- BIRC6 | c.10511G>A p.S3504N | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70196128; called by muse, mutect2, varscan2
- BRD2 | c.517T>C p.F173L | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137960007; called by muse, mutect2, varscan2
- CA9 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 130/215 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV65675075; called by muse, mutect2, varscan2
- CASQ2 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 80/387 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54767998, COSV99798159; called by muse, mutect2, varscan2
- CCDC141 | c.3880T>G p.F1294V | Missense Mutation (SNP) | VAF 30/405 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55369674; called by muse, mutect2
- CDC42EP1 | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs757357232, COSV50755688; called by muse, mutect2, varscan2
- COL19A1 | c.2114G>T p.G705V | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59566713; called by muse, mutect2, varscan2
- CSPG5 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1559615007, COSV53130220; called by muse, mutect2, varscan2
- CYRIB | c.429T>G p.D143E | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67828745; called by muse, mutect2, varscan2
- DENND11 | c.1290C>G p.D430E | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72097592; called by muse, mutect2, varscan2
- DLC1 | c.2960G>C p.G987A (on ENST00000276297 / NM_001348081.2; = p.G550A on NM_006094.5) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV52292232, COSV99365364; called by muse, mutect2, varscan2
- FAM217A | c.103G>C p.V35L | Missense Mutation (SNP) | VAF 47/464 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as rs771094326; called by muse, mutect2
- FAT1 | c.3131A>G p.K1044R | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV71672234; called by muse, mutect2, varscan2
- FBXW8 | c.1358G>A p.R453H (on ENST00000309909; = p.R491H on NM_012174.1) | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs368052577; called by muse, mutect2, varscan2
- GREB1 | c.4966G>A p.V1656I | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52181895; called by muse, mutect2, varscan2
- HECTD4 | c.12080G>C p.C4027S | Missense Mutation (SNP) | VAF 97/351 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV66387527; called by muse, mutect2, varscan2
- KCNJ15 | c.465G>T p.L155F | Missense Mutation (SNP) | VAF 154/267 reads (58%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as COSV60810330; called by muse, mutect2, varscan2
- KCNN3 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV55213152; called by muse, mutect2, varscan2
- KHDRBS1 | c.772-1G>A p.X258_splice | Splice Site (SNP) | VAF 24/115 reads (21%) | catalogued as COSV56981207, COSV56983702; called by muse, mutect2, varscan2
- LCOR | c.3022G>A p.A1008T | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV53714590; called by muse, mutect2, varscan2
- LINGO3 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV68261207; called by muse, mutect2, varscan2
- MARF1 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as rs757406736, COSV60019547; called by muse, mutect2
- MIEF1 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 92/427 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV57477721; called by muse, mutect2, varscan2
- MYH7B | c.1433G>C p.R478P | Missense Mutation (SNP) | VAF 66/448 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53417076; called by muse, mutect2, varscan2
- NLRP5 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as rs771977909, COSV66761889; called by muse, mutect2
- NOTCH3 | c.2088C>A p.S696R | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1422017339, COSV54627851; called by muse, mutect2, varscan2
- OR6C2 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.375); catalogued as rs772689823, COSV59515629; called by muse, mutect2, varscan2
- PI16 | c.576C>G p.C192W | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65447964; called by muse, mutect2, varscan2
- PLEKHG4B | c.3647C>T p.S1216F (on ENST00000283426; = p.S1572F on NM_052909.5) | Missense Mutation (SNP) | VAF 220/852 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs147897190, COSV52044299; called by muse, mutect2, varscan2
- PROC | c.401-3C>T | Splice Region (SNP) | VAF 22/306 reads (7%) | catalogued as rs1166802323; called by muse, mutect2
- PXDNL | c.2779C>G p.P927A | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV62497829; called by muse, mutect2, varscan2
- SLC12A4 | c.239C>G p.S80W | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57925852; called by muse, mutect2, varscan2
- SLC22A2 | c.724C>G p.Q242E | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65265773; called by muse, mutect2, varscan2
- SLC27A4 | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 164/371 reads (44%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.474); catalogued as rs759491973, COSV55958956; called by muse, mutect2, varscan2
- SLC5A6 | c.700G>C p.V234L | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.061); catalogued as COSV60158586; called by muse, mutect2, varscan2
- SMAD6 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 148/229 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56593627; called by muse, mutect2, varscan2
- SNX25 | c.1555-2A>G p.X519_splice | Splice Site (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99252686; called by muse, mutect2, varscan2
- SPATA2 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 144/380 reads (38%) | catalogued as COSV56865626; called by muse, mutect2, varscan2
- STK38L | c.108T>G p.I36M | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.127); catalogued as COSV66520684; called by muse, mutect2, varscan2
- TCHH | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 53/398 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV64273275; called by muse, mutect2, varscan2
- TNKS1BP1 | c.839C>G p.S280* | Nonsense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as COSV64100178; called by muse, mutect2, varscan2
- TPR | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV66599718; called by muse, mutect2, varscan2
- TYRO3 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs946916314, COSV55481143; called by muse, mutect2, varscan2
- VAMP1 | c.289-1G>C p.X97_splice | Splice Site (SNP) | VAF 27/157 reads (17%) | catalogued as COSV56946056, COSV99868842; called by muse, mutect2, varscan2
- VAV1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 117/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58379535; called by muse, mutect2, varscan2
- VCPIP1 | c.1231_1234del p.L411Gfs*34 | Frame Shift Del (DEL) | VAF 47/309 reads (15%) | catalogued as rs781116776; called by pindel, varscan2
- ZNF33B | c.1526A>G p.K509R | Missense Mutation (SNP) | VAF 90/443 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV63941950; called by muse, mutect2, varscan2
- ZNF761 | c.2006A>T p.K669M | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61887703; called by muse, mutect2, varscan2
- ZNF844 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV71518178; called by muse, mutect2, varscan2
- CCDC122 | c.822_*8del | Nonstop Mutation (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- CHD7 | c.2590_2595del p.G864_Q865del | In Frame Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel, varscan2
- FOSB | c.289T>G p.Y97D | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIAA0319L | c.1657-32_1659del p.X553_splice | Splice Site (DEL) | VAF 40/214 reads (19%) | called by mutect2, pindel, varscan2
- MAZ | c.529G>C p.A177P | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MGAM | c.4658G>C p.G1553A | Missense Mutation (SNP) | VAF 13/397 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MLNR | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, varscan2
- NCDN | c.2021dup p.S675Qfs*79 | Frame Shift Ins (INS) | VAF 155/425 reads (36%) | called by mutect2, pindel, varscan2
- PARP9 | c.823del p.I275Ffs*4 | Frame Shift Del (DEL) | VAF 113/403 reads (28%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.2878_2894delinsCT p.E960_T965delinsL | In Frame Del (DEL) | VAF 36/255 reads (14%) | called by pindel, varscan2*
- PRR35 | c.836del p.G279Afs*24 | Frame Shift Del (DEL) | VAF 50/163 reads (31%) | called by mutect2, pindel, varscan2
- WDR62 | c.2321G>A p.S774N | Missense Mutation (SNP) | VAF 28/718 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- ADGRG7 | c.594T>G p.P198= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV56294068; called by muse, mutect2, varscan2
- ASXL1 | c.2175A>G p.R725= | Silent (SNP) | VAF 75/456 reads (16%) | catalogued as COSV60103974; called by muse, mutect2, varscan2
- ATXN2 | c.2469A>G p.R823= (on ENST00000550104; = p.R663= on NM_002973.4) | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as COSV66481598; called by muse, mutect2, varscan2
- CAMTA2 | c.3198G>A p.R1066= | Silent (SNP) | VAF 48/243 reads (20%) | catalogued as COSV52776277; called by muse, mutect2, varscan2
- CDH5 | c.2172C>T p.P724= | Silent (SNP) | VAF 33/617 reads (5%) | catalogued as COSV58515554; called by muse, mutect2
- CNKSR3 | c.522G>A p.A174= | Silent (SNP) | VAF 55/189 reads (29%) | catalogued as rs756717380, COSV70480767; called by muse, mutect2, varscan2
- ERICH6B | c.1587C>A p.I529= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV53918192; called by muse, mutect2, varscan2
- HRAS | c.96C>T p.Y32= | Silent (SNP) | VAF 138/286 reads (48%) | catalogued as rs369039481, COSV54236910; ClinVar: likely benign; called by mutect2, varscan2
- KCNA4 | c.762G>A p.E254= | Silent (SNP) | VAF 8/223 reads (4%) | called by muse, mutect2
- MOGS | c.1170G>A p.L390= | Silent (SNP) | VAF 37/281 reads (13%) | catalogued as COSV51968387; called by muse, mutect2, varscan2
- MRPL52 | c.198A>G p.R66= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV61287643; called by muse, mutect2, varscan2
- MRPS7 | c.666G>A p.R222= | Silent (SNP) | VAF 103/347 reads (30%) | catalogued as COSV55452951; called by muse, mutect2, varscan2
- NRTN | c.567G>A p.L189= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- NWD1 | c.1389C>T p.H463= | Silent (SNP) | VAF 132/282 reads (47%) | catalogued as COSV60338297; called by muse, mutect2, varscan2
- POLR1A | c.201C>T p.C67= | Silent (SNP) | VAF 147/393 reads (37%) | catalogued as rs1209136092, COSV55689769; called by muse, varscan2
- POLR1A | c.153C>T p.Y51= | Silent (SNP) | VAF 49/421 reads (12%) | catalogued as rs370186256; called by muse, varscan2
- PRPH2 | c.939G>A p.P313= | Silent (SNP) | VAF 51/376 reads (14%) | catalogued as rs1052492384, COSV57836325; called by muse, mutect2, varscan2
- RBM23 | c.579C>T p.R193= (on ENST00000359890 / NM_001077351.2; = p.R177= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/172 reads (50%) | catalogued as rs778516935, COSV57127060; called by muse, mutect2, varscan2
- RGL1 | c.334C>T p.L112= (on ENST00000360851 / NM_001297672.2; = p.L147= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/212 reads (18%) | catalogued as COSV58979645, COSV58994433; called by muse, mutect2, varscan2
- RMND1 | c.822A>T p.I274= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV60550047; called by muse, mutect2, varscan2
- SGK3 | c.651T>C p.N217= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as COSV61893840; called by muse, mutect2, varscan2
- SLC2A4 | c.774T>C p.A258= | Silent (SNP) | VAF 185/622 reads (30%) | catalogued as COSV50300474; called by muse, mutect2, varscan2
- SLCO1C1 | c.1230G>C p.G410= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as COSV56869099, COSV56878418; called by muse, mutect2, varscan2
- SRRM1 | c.327G>A p.L109= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV60475541; called by muse, mutect2, varscan2
- TTF2 | c.2751G>A p.L917= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs1198948436, COSV65632124; called by muse, mutect2, varscan2
- ANKMY1 | chr2:240560729 A>T | 5'Flank (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- CDK16 | c.-375G>A | 5'UTR (SNP) | VAF 36/111 reads (32%) | catalogued as rs1246755974, COSV52093572; called by muse, mutect2, varscan2
- CPLANE1 | c.*5908G>T | 3'UTR (SNP) | VAF 36/273 reads (13%) | catalogued as COSV57053880; called by muse, mutect2, varscan2
- EGFEM1P | n.555C>G | RNA (SNP) | VAF 20/132 reads (15%) | catalogued as rs748685212; called by muse, mutect2, varscan2
- HMG20B | c.*332C>A | 3'UTR (SNP) | VAF 75/170 reads (44%) | catalogued as COSV53571464, COSV53571776; called by muse, mutect2, varscan2
- LINC01630 | n.210C>T | RNA (SNP) | VAF 38/157 reads (24%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+565G>C | Intron (SNP) | VAF 118/355 reads (33%) | catalogued as COSV60570946; called by muse, mutect2, varscan2
- NAP1L1 | c.1090-211_1090-206dup | Intron (INS) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- NPIPB10P | n.976C>G | RNA (SNP) | VAF 258/588 reads (44%) | called by muse, varscan2
- PAX3 | chr2:222201230 T>C | 3'Flank (SNP) | VAF 73/248 reads (29%) | catalogued as COSV60586478; called by muse, varscan2
- PITX2 | c.390+147C>A | Intron (SNP) | VAF 196/312 reads (63%) | catalogued as rs1359241296, COSV60740343; called by muse, mutect2, varscan2
- RPN2 | c.-24C>T | 5'UTR (SNP) | VAF 66/229 reads (29%) | catalogued as COSV52904023; called by muse, mutect2, varscan2
